Somatic mutation profile of tumor specimen MP2PRT-PAPTME-TMP1-A (aliquot MP2PRT-PAPTME-TMP1-A-1-0-D-A83N-36) from MP2PRT case MP2PRT-PAPTME, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Primary diagnosis: Leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.9 years (1,048 days).
Specimen MP2PRT-PAPTME-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 452f3975-9e9e-4090-8635-93456139fda7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPTME-NM1-A (Blood Derived Cancer - Bone Marrow, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPTME-NM1-A-1-0-D-A83N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f16c4a6e-5194-4a76-8e7a-6e5cb4bf3369

The open-access MAF lists 23 somatic variants for this specimen: 15 protein-altering or splice-affecting, 7 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 7, Nonsense Mutation 2, Splice Region 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADNP2 | c.295G>A p.E99K | Missense Mutation (SNP) | VAF 36/411 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.526); catalogued as rs1335780989; called by muse, mutect2
- ATP10A | c.3229C>T p.H1077Y | Missense Mutation (SNP) | VAF 26/372 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV63522454; called by muse, mutect2
- BLMH | c.1261G>A p.E421K | Missense Mutation (SNP) | VAF 43/419 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1480557860, COSV55585417; called by muse, mutect2
- COL7A1 | c.1474G>A p.E492K | Missense Mutation (SNP) | VAF 44/417 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.917); catalogued as rs145343367; called by muse, mutect2, varscan2
- DAB1 | c.644C>T p.T215M | Missense Mutation (SNP) | VAF 59/209 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.183); catalogued as rs149741427; called by muse, mutect2, varscan2
- DSG1 | c.966G>A p.M322I | Missense Mutation (SNP) | VAF 8/206 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.296); catalogued as COSV57133919; called by muse, mutect2
- FDXR | c.158C>T p.T53M | Missense Mutation (SNP) | VAF 94/319 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs199819323; called by muse, mutect2, varscan2
- H3C10 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 37/403 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.904); catalogued as COSV60797298, COSV60799019; called by muse, mutect2
- HTR1A | c.1078C>G p.P360A | Missense Mutation (SNP) | VAF 67/485 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV60500312; called by muse, mutect2, varscan2
- MECR | c.718G>A p.E240K | Missense Mutation (SNP) | VAF 17/416 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.093); catalogued as COSV55285703; called by muse, mutect2
- NRXN3 | c.1981G>A p.G661S (on ENST00000335750 / NM_001330195.2; = p.G288S on NM_004796.6) | Missense Mutation (SNP) | VAF 129/420 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs776109442, COSV59778101, COSV59781225; called by muse, mutect2, varscan2
- SLC30A1 | c.1081C>T p.R361* | Nonsense Mutation (SNP) | VAF 76/290 reads (26%) | catalogued as COSV65360582; called by muse, mutect2, varscan2
- MROH2B | c.30G>A p.E10= | Splice Region (SNP) | VAF 64/229 reads (28%) | called by muse, mutect2, varscan2
- NYX | c.181C>T p.P61S | Missense Mutation (SNP) | VAF 55/492 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SVIP | c.222G>A p.W74* | Nonsense Mutation (SNP) | VAF 10/180 reads (6%) | called by muse, mutect2
- ASTN2 | c.964C>T p.L322= | Silent (SNP) | VAF 16/450 reads (4%) | catalogued as COSV100528087; called by muse, mutect2
- CCM2L | c.1170C>T p.S390= (on ENST00000452892 / NM_001365692.1; = p.A369V on NM_080625.4) | Silent (SNP) | VAF 86/315 reads (27%) | catalogued as rs139147006, COSV52952552; called by muse, varscan2
- DCAF12L2 | c.609G>A p.L203= | Silent (SNP) | VAF 38/828 reads (5%) | called by muse, mutect2
- GPR32 | c.888C>T p.L296= | Silent (SNP) | VAF 22/506 reads (4%) | called by muse, mutect2
- MAN2A1 | c.852C>T p.S284= | Silent (SNP) | VAF 107/323 reads (33%) | catalogued as rs745391637, COSV54846383; called by muse, mutect2, varscan2
- SETD2 | c.4938G>A p.L1646= | Silent (SNP) | VAF 10/312 reads (3%) | called by muse, mutect2
- SPAG17 | c.3798G>A p.V1266= | Silent (SNP) | VAF 17/382 reads (4%) | called by muse, mutect2
- AL353804.7 | n.32G>C | RNA (SNP) | VAF 87/322 reads (27%) | called by muse, mutect2, varscan2
